Gene-level copy-number profile of tumor specimen ALCH-B2P1-TTP1-A from ALCHEMIST case ALCH-B2P1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.2 years (23,809 days).
Specimen ALCH-B2P1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d50e980a-4897-4913-aaf5-0d151e353d75.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2P1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/ba8fe177-10f8-4347-8950-2cc0b7d7a759

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 609; copy number 1: 8,380; copy number 2: 47,154; copy number 3: 2,593; copy number 4: 145; copy number 5: 6; copy number 6: 1; copy number 7: 6; copy number 8: 1; copy number 9: 1; copy number 11: 2; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,727,117–31,764,893, 2 genes: ADGRB2, MIR4254.
- chr2:85,751,344–85,791,383, 2 genes: ATOH8, MIR6071.
- chr2:131,442,644–131,521,573, 7 genes: NOC2LP2, RHOQP2, AC073869.1, MZT2A, TUBA3D, MIR4784, SMPD4BP.
- chr3:141,936,707–141,938,547, 1 gene: AC112504.1.
- chr5:139,647,299–139,683,882, 2 genes (within-gene range 0–2): CXXC5, CXXC5-AS1.
- chr7:44,104,345–44,114,562, 2 genes: AEBP1, MIR4649.
- chr7:76,978,617–77,004,308, 1 gene (within-gene range 0–2): DTX2P1.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr9:42,579,414–42,668,887, 4 genes: BX088651.2, FGF7P5, BX088651.3, FGF7P4.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr11:77,066,961–77,126,155, 2 genes: CAPN5, OMP.
- chr11:133,896,438–133,956,968, 1 gene (within-gene range 0–2): IGSF9B.
- chr15:25,174,927–25,220,578, 25 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:85,744,109–85,794,925, 6 genes (within-gene range 0–2): AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:1,329,078–1,329,777, 1 gene: RPS20P2.
- chr16:66,802,875–67,019,817, 14 genes: NAE1, AC044802.2, CA7, PDP2, CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3, CES4A, AC009084.2, RN7SL543P.
- chr16:84,009,667–84,045,333, 3 genes: SLC38A8, RNA5SP432, AC040169.4.
- chr17:3,896,592–3,964,464, 2 genes: P2RX1, ATP2A3.
- chr17:75,818,815–75,820,055, 1 gene (within-gene range 0–1): AC087289.1.
- chr17:79,132,722–79,136,402, 1 gene (within-gene range 0–1): AC021534.1.
- chr20:25,248,085–25,298,012, 3 genes (within-gene range 0–2): PYGB, AL121772.2, AL121772.3.
- chr22:18,873,543–18,894,407, 2 genes: FAM230F, AC008103.1.
- chr22:50,170,731–50,261,716, 10 genes: PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,401,909–1,410,618, 3 genes, copy number 5 (within-gene range 2–5): MRPL20, RN7SL657P, MRPL20-DT.
- chr3:196,739,857–196,832,647, 1 gene, copy number 5 (within-gene range 3–5): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 5: RNU6-42P.
- chr6:112,070,663–112,087,529, 1 gene, copy number 5 (within-gene range 2–5): TUBE1.
- chr11:112,967–139,612, 3 genes, copy number 7 (within-gene range 5–7): AC069287.1, CICP23, LINC01001.
- chr16:33,533,816–33,545,812, 2 genes, copy number 14: AC136944.1, AC136944.2.
- chr21:43,461,960–43,479,534, 1 gene, copy number 8 (within-gene range 2–8): LINC00313.
- chr22:18,733,914–18,861,049, 4 genes, copy number 6–11: FAM230E, E2F6P1, AC008132.1, BCRP7.
- chr22:18,906,028–18,947,732, 3 genes, copy number 7 (within-gene range 1–7): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 6,049. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
